Surgical pathology report (de-identified scan), TCGA case TCGA-RW-A67W, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Michigan University, specimen TCGA-RW-A67W-01A (Primary Tumor).

PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:

PATIENT NBR:

PAGE #: 1
SEX: F

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE: SPHS

Endurance athlete with palpitations and anxiety a couple times per week. Scan noted incidental right adrenal mass. Clinical Diagnosis: Pheochromocytoma. Operative Procedure/Tissue Submitted: Laparoscopic right adrenalectomy.

PROCEDURE: SPGD

VERIFIED BY

1. "Right adrenal gland" Received in formalin in a small container is an 8 gram, 5 x 3.8 x 1.3 cm adrenal gland with a 1.7 x 1.3 x 1 cm. On cut surface the nodule is uniformly tan with an apparent lobulated architecture. The nodule grossly extends to the surgical margin. Please see pictures.
- 1A-C. Serial sections of nodule.
- 1D. Representative sections of apparently uninvolved adrenal gland.

PROCEDURE: SPDY

VERIFIED BY:

1. Right adrenal gland, excision: Pheochromocytoma (1.7 cm), confined to the adrenal gland.

I, _____, the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

IRPAA Discrepancy		/

Source: NCI Genomic Data Commons file d8323054-9d5d-4919-b469-6c24cf786f87 (TCGA-RW-A67W.C4401BCF-A726-4C07-8E72-9710EEAA3497.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).